Somatic mutation profile of tumor specimen TCGA-DX-A7EQ-01A (aliquot TCGA-DX-A7EQ-01A-11D-A387-09) from TCGA case TCGA-DX-A7EQ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 72.6 years (26,503 days).
Specimen TCGA-DX-A7EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff317c3-3875-4310-bb5f-fdf5491712ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EQ-11B (Solid Tissue Normal), aliquot TCGA-DX-A7EQ-11B-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75d51af7-14b3-442c-9366-ae6523b3930d

The open-access MAF lists 42 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1306009113, COSV99570865; called by muse, mutect2, varscan2
- AKR1D1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV54340238; called by muse, mutect2, varscan2
- ANK2 | c.11041G>A p.V3681I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV100004210; called by muse, mutect2, varscan2
- BOLL | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs915401766, COSV99987427; called by muse, mutect2, varscan2
- BRD8 | c.803C>T p.S268F (on ENST00000254900 / NM_139199.2; = p.S341F on NM_006696.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99137648; called by muse, mutect2, varscan2
- CFAP157 | c.365A>C p.Q122P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100077087; called by muse, mutect2, varscan2
- CHRNA10 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99167256; called by muse, mutect2, varscan2
- COL24A1 | c.2801T>C p.L934P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100993978; called by muse, mutect2, varscan2
- EEF1A1 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV100303445; called by muse, mutect2, varscan2
- EHBP1 | c.1754A>G p.Y585C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772349202, COSV99861875; called by muse, mutect2, varscan2
- FCF1 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV100356879; called by muse, mutect2, varscan2
- GABRP | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558177227, COSV54661976; called by muse, mutect2, varscan2
- GPR132 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100317731; called by muse, mutect2, varscan2
- GPR158 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377328410; called by muse, mutect2, varscan2
- HIPK1 | c.2119C>A p.L707I | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV100479661; called by muse, mutect2, varscan2
- KIF1B | c.3650G>A p.R1217H (on ENST00000377086 / NM_001365952.1; = p.R1171H on NM_015074.3) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99824175; called by muse, mutect2, varscan2
- LGALS7B | c.285C>G p.D95E | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100153384, COSV100153414; called by muse, mutect2
- MIER2 | c.1617-2A>T p.X539_splice | Splice Site (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99316752; called by muse, mutect2, varscan2
- MMP25 | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100339619; called by muse, mutect2
- MTRF1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99520990; called by muse, mutect2, varscan2
- PBX3 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100655591; called by muse, mutect2, varscan2
- PITPNM1 | c.3652C>T p.R1218C | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.23); catalogued as rs778239395, COSV99653836; called by muse, mutect2, varscan2
- PREX2 | c.3400C>A p.H1134N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.346); catalogued as COSV55767050, COSV99909917; called by muse, mutect2
- PSG1 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.363); catalogued as COSV99741366; called by muse, mutect2, varscan2
- RICTOR | c.646A>C p.I216L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99705732; called by muse, mutect2, varscan2
- SPTB | c.2410C>T p.Q804* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV67636042; called by muse, mutect2, varscan2
- STAG1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs1435519890, COSV52603061; called by muse, mutect2, varscan2
- SVBP | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1298713483, COSV100997897; called by muse, mutect2
- TTN | c.70697C>T p.P23566L (on ENST00000591111; = p.P16142L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen possibly damaging (0.676); catalogued as COSV100629703; called by muse, mutect2, varscan2
- ZFP30 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as rs541723751, COSV100665783, COSV100666083; called by muse, mutect2, varscan2
- ZNF2 | c.530G>A p.R177K (on ENST00000611147 / NM_001291605.2; = p.R164K on NM_021088.4) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752460653, COSV54638159; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2309G>C p.R770P | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCTD21 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.73); called by muse, mutect2
- SYNDIG1 | c.619-16_641del p.X207_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel
- ZHX2 | c.801del p.Y267* | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- ABR | c.1080C>T p.P360= (on ENST00000302538 / NM_021962.5; = p.P323= on NM_001092.5) | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs199545490, COSV52142631; called by muse, mutect2, varscan2
- CYP4F12 | c.1512G>A p.L504= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as rs1336840844, COSV61175606; called by muse, mutect2
- ERBB2 | c.435C>T p.L145= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV54073095; called by muse, mutect2
- OTOP2 | c.1335C>T p.D445= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100173048; called by muse, mutect2, varscan2
- SEMA4D | c.654A>G p.R218= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100358801; called by muse, mutect2, varscan2
- SLC26A9 | c.972G>A p.S324= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs147218911, COSV61606151; called by muse, mutect2, varscan2
- ZNF862 | c.772C>T p.L258= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1220056522, COSV99783817; called by muse, mutect2, varscan2
